Somatic mutation profile of tumor specimen TCGA-56-8082-01A (aliquot TCGA-56-8082-01A-11D-2244-08) from TCGA case TCGA-56-8082, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.6 years (29,440 days).
Specimen TCGA-56-8082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6bb3d78-c6b8-4bf7-b7eb-998cfd740b47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8082-10A (Blood Derived Normal), aliquot TCGA-56-8082-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e669dfe1-79b9-4dff-8a2f-dcf50edce47b

The open-access MAF lists 236 somatic variants for this specimen: 170 protein-altering or splice-affecting, 59 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 59, Nonsense Mutation 11, Frame Shift Del 5, Intron 4, Splice Region 3, Splice Site 3, 5'Flank 2, Frame Shift Ins 1, RNA 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC134980.2 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV100171454; called by muse, mutect2, varscan2
- ADAM23 | c.1953C>A p.S651R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100006718; called by muse, mutect2, varscan2
- ADGRB3 | c.594C>A p.C198* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV100999474, COSV100999818; called by muse, mutect2, varscan2
- ADGRG7 | c.2374A>G p.N792D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99840549; called by muse, mutect2, varscan2
- AL645922.1 | c.3698A>T p.Q1233L | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100963746; called by muse, mutect2, varscan2
- ALAS2 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.768); catalogued as COSV100237980; called by muse, mutect2, varscan2
- ALG2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99445388; called by muse, mutect2, varscan2
- ANK1 | c.2947G>T p.A983S | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs113676296; called by muse, mutect2, varscan2
- ANK2 | c.10267G>A p.E3423K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV99999852; called by muse, mutect2, varscan2
- ANKK1 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100392696; called by muse, mutect2, varscan2
- ANKRD30A | c.511-1G>T p.X171_splice (on ENST00000611781; = p.X115_splice on NM_052997.2) | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100652956, COSV64609404; called by muse, mutect2, varscan2
- ANKRD30A | c.511G>T p.A171S (on ENST00000611781; = p.A115S on NM_052997.2) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.983); catalogued as COSV100652957; called by muse, mutect2, varscan2
- APC | c.7481C>T p.S2494F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99965387; called by muse, mutect2, varscan2
- APEX2 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV100895152; called by muse, mutect2, varscan2
- BMP5 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 198/298 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100895771; called by muse, varscan2
- CAMSAP1 | c.2390G>A p.S797N | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100409582; called by muse, mutect2, varscan2
- CARD10 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99324623; called by muse, mutect2, varscan2
- CCRL2 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100644972; called by muse, mutect2, varscan2
- CD53 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99602094, COSV99602173; called by muse, mutect2, varscan2
- CDH9 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV50276932, COSV99141765; called by muse, mutect2, varscan2
- CLCA2 | c.1279G>C p.G427R | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as COSV100991356; called by muse, mutect2, varscan2
- CNBD1 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV72976888; called by muse, mutect2, varscan2
- CNGA2 | c.445A>T p.M149L | Missense Mutation (SNP) | VAF 137/319 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100323390; called by muse, mutect2, varscan2
- COL11A1 | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615232; called by muse, mutect2, varscan2
- COL3A1 | c.4257A>T p.K1419N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV100482508; called by muse, mutect2, varscan2
- COL6A6 | c.5703C>G p.S1901R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100649831; called by muse, mutect2, varscan2
- CPA3 | c.30T>G p.I10M | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99935970; called by muse, mutect2, varscan2
- CPA4 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV99744648; called by muse, mutect2, varscan2
- CSTF2 | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100880634; called by muse, mutect2, varscan2
- CYFIP1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs768964942; called by muse, mutect2
- CYP3A7 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs774768130, COSV60481775; called by muse, mutect2
- DCTN4 | c.1253G>T p.C418F | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101437533; called by muse, mutect2, varscan2
- DDX10 | c.2541G>T p.R847S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100489060; called by muse, mutect2, varscan2
- DELE1 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99519648; called by muse, mutect2, varscan2
- DLL1 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100815900, COSV100815923; called by muse, mutect2, varscan2
- DNAJC22 | c.592T>A p.Y198N | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101222496; called by muse, mutect2, varscan2
- DOCK11 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.4); catalogued as COSV99352932; called by muse, mutect2, varscan2
- DOCK2 | c.5212C>A p.H1738N | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.067); catalogued as COSV99910419; called by muse, varscan2
- DOK1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); catalogued as COSV99283935; called by muse, mutect2, varscan2
- DSCAML1 | c.1802A>G p.D601G (on ENST00000321322; = p.D541G on NM_020693.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100354660; called by muse, mutect2, varscan2
- DTD1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101079674; called by mutect2, varscan2
- DYSF | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV50458672; called by muse, mutect2, varscan2
- E2F1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100593902; called by muse, mutect2, varscan2
- ECI2 | c.312G>A p.K104= (on ENST00000380118 / NM_206836.3; = p.K74= on NM_006117.2) | Splice Region (SNP) | VAF 60/159 reads (38%) | catalogued as COSV100326314; called by muse, mutect2, varscan2
- ENPEP | c.1907G>T p.W636L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99487101; called by muse, mutect2, varscan2
- EPN1 | c.1643A>T p.Y548F (on ENST00000270460 / NM_001321263.1; = p.Y522F on NM_013333.3) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99321570; called by muse, mutect2
- EVX2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100420555; called by muse, mutect2
- FBH1 | c.206A>T p.Q69L (on ENST00000362091 / NM_178150.3; = p.Q120L on NM_032807.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100758613; called by muse, mutect2, varscan2
- FCRL2 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100829832; called by muse, mutect2, varscan2
- FSCB | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 26/30 reads (87%) | catalogued as COSV100468875; called by muse, mutect2, varscan2
- GABRA2 | c.548A>T p.K183I | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100733847, COSV100734191; called by muse, mutect2, varscan2
- GALNT2 | c.1471A>T p.K491* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100795450; called by muse, mutect2, varscan2
- GDF9 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV51526710, COSV99737111; called by muse, mutect2, varscan2
- GJB5 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as rs759366017, COSV100258276, COSV58356988; called by muse, mutect2, varscan2
- GLMP | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99827753; called by muse, varscan2
- GLRB | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52416171, COSV52419333; called by muse, mutect2, varscan2
- GLUD2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100046616; called by muse, mutect2, varscan2
- GPR55 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV101235713; called by muse, mutect2, varscan2
- GPR85 | c.887C>A p.T296N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99775065; called by muse, mutect2, varscan2
- GXYLT2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144493258, COSV67473304; called by muse, mutect2, varscan2
- HK3 | c.2341C>A p.R781S | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.58); PolyPhen benign (0.035); catalogued as COSV99457858; called by muse, mutect2, varscan2
- IRGC | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV54984446, COSV54985188; called by muse, mutect2, varscan2
- ITIH6 | c.3167T>A p.M1056K | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV99512859; called by muse, mutect2, varscan2
- ITPRID2 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100237900; called by muse, mutect2, varscan2
- KANSL1L | c.2189A>G p.Q730R | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV99910187; called by muse, mutect2, varscan2
- KCNH1 | c.1428G>C p.E476D (on ENST00000271751 / NM_172362.3; = p.E449D on NM_002238.4) | Missense Mutation (SNP) | VAF 117/334 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55074748, COSV55086603; called by muse, mutect2, varscan2
- KCNIP4 | c.276A>T p.R92S | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100749061; called by muse, mutect2, varscan2
- KIAA0586 | c.4107A>C p.Q1369H (on ENST00000619416 / NM_001244190.2; = p.Q1308H on NM_014749.5) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV99707533; called by muse, mutect2, varscan2
- KIAA1109 | c.1191G>C p.L397F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99145881; called by muse, mutect2, varscan2
- KIF7 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs775526351; called by muse, mutect2, varscan2
- KMT2B | c.2226G>C p.Q742H | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as rs780838391, COSV99385863; called by muse, mutect2, varscan2
- KMT2B | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.034); catalogued as COSV99385864; called by muse, mutect2, varscan2
- KMT2C | c.1078A>T p.T360S | Missense Mutation (SNP) | VAF 54/502 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); catalogued as COSV100067246; called by muse, varscan2
- KRT76 | c.600+1G>T p.X200_splice | Splice Site (SNP) | VAF 44/159 reads (28%) | catalogued as COSV100195905; called by muse, mutect2, varscan2
- KRTAP5-5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 65/170 reads (38%) | PolyPhen benign (0.36); catalogued as rs1162708562, COSV101294144; called by muse, mutect2, varscan2
- LCP1 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV100549697; called by muse, mutect2, varscan2
- LGSN | c.1189T>C p.C397R | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV101040277; called by muse, mutect2, varscan2
- LRRC15 | c.1348G>T p.V450L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100752547; called by muse, mutect2, varscan2
- MAGEA1 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV100756605; called by muse, mutect2, varscan2
- MDN1 | c.7793G>A p.R2598Q | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs149622123; called by muse, mutect2, varscan2
- METAP1D | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV100249812, COSV59932453; called by muse, mutect2, varscan2
- MGLL | c.853G>A p.E285K (on ENST00000398104 / NM_001003794.2; = p.E295K on NM_007283.6) | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99411466; called by muse, mutect2, varscan2
- MIP | c.791A>G p.*264Wext*19 | Nonstop Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as rs1249590446, COSV57512033, COSV99234110; called by muse, mutect2, varscan2
- MMS22L | c.290+1G>A p.X97_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99246119; called by muse, mutect2, varscan2
- MRC1 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509498; called by muse, mutect2, varscan2
- MYH2 | c.4971G>A p.K1657= | Splice Region (SNP) | VAF 73/95 reads (77%) | catalogued as COSV55433441, COSV99820949; called by muse, mutect2, varscan2
- NCAN | c.2585A>T p.Q862L | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV99386584; called by muse, mutect2, varscan2
- NECAP1 | c.667A>G p.S223G | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100331526; called by muse, mutect2, varscan2
- NEU1 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs888823649, COSV99998621; called by muse, mutect2, varscan2
- NEXMIF | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99279690; called by muse, mutect2, varscan2
- NOTCH3 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs749561286, COSV54625264; called by muse, mutect2, varscan2
- NPY5R | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 100/161 reads (62%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.886); catalogued as COSV100642649; called by muse, mutect2, varscan2
- NR1D1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs148810425; called by muse, mutect2, varscan2
- OR1C1 | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101376183; called by muse, mutect2, varscan2
- OR4K1 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99578666; called by muse, mutect2, varscan2
- OR52K2 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.527); catalogued as COSV100355638; called by muse, mutect2, varscan2
- OR8H1 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100476845; called by muse, mutect2, varscan2
- OR8J1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100274871, COSV57318743; called by muse, mutect2, varscan2
- P3H1 | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 38/53 reads (72%) | catalogued as COSV99354839; called by muse, mutect2, varscan2
- PAFAH1B2 | c.53T>A p.I18N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV100505839; called by muse, mutect2, varscan2
- PCDHA3 | c.1739T>C p.L580P | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as rs782015955, COSV100793166; called by muse, mutect2, varscan2
- PCDHB11 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 98/159 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100696901; called by muse, mutect2, varscan2
- PCNX1 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV99454118; called by muse, mutect2
- PHKA2 | c.2938C>G p.P980A | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV101176643, COSV66056491; called by muse, mutect2, varscan2
- PIWIL1 | c.887A>C p.Q296P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99806006; called by muse, mutect2, varscan2
- PKHD1L1 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.076); catalogued as rs373602773, COSV101005429; called by muse, mutect2, varscan2
- PLXNA3 | c.4810A>C p.T1604P | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); catalogued as COSV100859815; called by muse, mutect2, varscan2
- PPFIA2 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100331732, COSV61026670; called by muse, mutect2
- PPM1L | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55563811, COSV99861339; called by muse, mutect2, varscan2
- PRTG | c.2108A>G p.D703G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.626); catalogued as COSV101221275; called by muse, mutect2, varscan2
- PUS3 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs779598027, COSV99916800; called by muse, varscan2
- RALBP1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.16); catalogued as COSV99191878; called by muse, mutect2, varscan2
- RASA3 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100479850; called by muse, mutect2, varscan2
- RBM45 | c.445T>C p.C149R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99617508; called by muse, mutect2, varscan2
- RCSD1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100827560; called by muse, mutect2, varscan2
- RFX4 | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99985383; called by muse, mutect2, varscan2
- RILPL1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as rs1183422842, COSV61553621; called by muse, mutect2, varscan2
- RPL10 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99185817; called by muse, mutect2, varscan2
- RPL10 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV99185818; called by muse, mutect2, varscan2
- RTCA | c.812A>T p.D271V | Missense Mutation (SNP) | VAF 84/103 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV99559552; called by muse, mutect2, varscan2
- RYR1 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614538, COSV62096061; called by muse, mutect2, varscan2
- SCN1A | c.5412C>A p.D1804E (on ENST00000303395 / NM_001202435.3; = p.D1793E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100319366; called by muse, mutect2, varscan2
- SEC22A | c.772T>A p.L258M | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100006813; called by muse, mutect2, varscan2
- SGPP2 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100346092; called by muse, mutect2, varscan2
- SIRPB2 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100708385, COSV100708480; called by muse, mutect2
- SLC13A5 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.7); PolyPhen benign (0.052); catalogued as rs777184227, COSV53421606; called by muse, mutect2, varscan2
- SLC3A1 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99576839, COSV99577089; called by muse, mutect2, varscan2
- SLCO1B1 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV99918008; called by muse, mutect2
- SLCO2B1 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99214281; called by muse, mutect2, varscan2
- SMAD4 | c.546C>G p.I182M | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.836); catalogued as COSV100747485; called by muse, mutect2, varscan2
- SOBP | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100432805; called by muse, mutect2, varscan2
- SPATA5 | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914793; called by muse, varscan2
- SPATA5 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV99914794; called by muse, varscan2
- SPOCD1 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99929462; called by muse, mutect2, varscan2
- SPTA1 | c.3938C>T p.S1313L | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV63759183; called by muse, mutect2, varscan2
- SVIL | c.6575C>T p.T2192M (on ENST00000355867 / NM_021738.3; = p.T1766M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs777862633, COSV63445654; called by muse, mutect2, varscan2
- SYN3 | c.1049C>A p.A350D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100248385; called by muse, mutect2, varscan2
- TAF3 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100719832; called by muse, mutect2, varscan2
- TAOK2 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs756975773, COSV54237344; called by muse, mutect2, varscan2
- TCHH | c.5770C>A p.P1924T | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.293); catalogued as COSV100914905, COSV100915144; called by muse, mutect2, varscan2
- TERT | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99716456; called by muse, mutect2, varscan2
- TEX45 | c.1481C>G p.P494R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV100861790; called by muse, mutect2, varscan2
- TJP1 | c.4129G>A p.A1377T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV100632336; called by muse, mutect2, varscan2
- TMEM132D | c.1273T>A p.L425M | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV101396511; called by muse, mutect2, varscan2
- TMEM187 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100890139; called by muse, mutect2, varscan2
- TNFRSF1A | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.25); catalogued as rs1005685583, COSV99369415; called by muse, mutect2, varscan2
- TP53BP2 | c.3315G>T p.W1105C (on ENST00000343537 / NM_001031685.3; = p.W976C on NM_005426.2) | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100636508; called by muse, mutect2, varscan2
- TRIM42 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99647993; called by muse, mutect2, varscan2
- TRPA1 | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100083217; called by muse, mutect2, varscan2
- TTN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | PolyPhen probably damaging (0.999); catalogued as COSV100595064; called by muse, mutect2, varscan2
- UBN2 | c.3047A>T p.K1016M | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs775865083, COSV99943639; called by muse, mutect2, varscan2
- UQCRFS1 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs769965262, COSV59184597; called by muse, mutect2, varscan2
- WDR4 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs200946434, COSV100375091; called by muse, varscan2
- WNK3 | c.4619T>A p.L1540* | Nonsense Mutation (SNP) | VAF 81/231 reads (35%) | catalogued as COSV100670808; called by muse, mutect2, varscan2
- WNT3A | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99468829; called by muse, mutect2, varscan2
- ZFR2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs773957821, COSV99507007; called by muse, varscan2
- ZMIZ1 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100565898; called by muse, mutect2, varscan2
- ZMYM3 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100077469; called by muse, mutect2, varscan2
- ZNF398 | c.1622G>T p.C541F (on ENST00000475153 / NM_170686.3; = p.C370F on NM_020781.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60064648, COSV60066119; called by muse, mutect2, varscan2
- ZNF471 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.459); catalogued as COSV100340375; called by muse, varscan2
- C3orf38 | c.422del p.L141Qfs*20 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- CAPN9 | c.1425_1426del p.H476Pfs*4 | Frame Shift Del (DEL) | VAF 43/198 reads (22%) | called by mutect2, pindel, varscan2
- GLT6D1 | c.522del p.N175Tfs*56 | Frame Shift Del (DEL) | VAF 33/82 reads (40%) | called by mutect2, pindel, varscan2
- IGKV6D-21 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- LTK | c.977del p.G326Efs*48 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- MUC2 | c.2445C>A p.P815= | Splice Region (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- OTOP1 | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- PON1 | c.698dup p.Y234Vfs*6 | Frame Shift Ins (INS) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- TP53 | c.540_557del p.E180_S185del | In Frame Del (DEL) | VAF 30/50 reads (60%) | called by mutect2, pindel, varscan2
- TP63 | c.1823_1836del p.H608Pfs*20 | Frame Shift Del (DEL) | VAF 91/242 reads (38%) | called by mutect2, pindel, varscan2
- ABCB1 | c.3210C>A p.G1070= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV99712187; called by muse, mutect2, varscan2
- ADD3 | c.265C>T p.L89= | Silent (SNP) | VAF 73/113 reads (65%) | catalogued as COSV99523191; called by muse, mutect2, varscan2
- AGAP3 | c.168C>A p.R56= (on ENST00000622464; = p.R92= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99880188; called by muse, mutect2, varscan2
- ANKRD30A | c.3231T>C p.D1077= (on ENST00000611781; = p.D1021= on NM_052997.2) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1173746283, COSV100652958; called by muse, mutect2, varscan2
- ARHGAP26 | c.1710C>T p.T570= | Silent (SNP) | VAF 147/223 reads (66%) | catalogued as rs367794102; called by muse, mutect2, varscan2
- CABP4 | c.204G>A p.G68= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100351433; called by muse, mutect2, varscan2
- CCDC170 | c.93G>A p.T31= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs1022977985, COSV53339583, COSV53340040; called by muse, mutect2, varscan2
- CCPG1 | c.1962T>C p.D654= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV51243527, COSV99380045; called by muse, mutect2, varscan2
- CD276 | c.1053C>G p.A351= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100573234, COSV100573290; called by muse, mutect2, varscan2
- CDH9 | c.411G>T p.R137= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as rs1292467358, COSV99141761; called by muse, mutect2, varscan2
- CHMP1B | c.447G>T p.V149= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV99303095; called by muse, mutect2, varscan2
- DES | c.1035G>A p.L345= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV100900324; called by muse, mutect2, varscan2
- DPYSL2 | c.795C>T p.A265= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as rs1178500013, COSV100233614, COSV60784273; called by muse, mutect2, varscan2
- DST | c.5746C>T p.L1916= | Silent (SNP) | VAF 19/185 reads (10%) | catalogued as rs775554670, COSV99751342; called by muse, mutect2
- DTD1 | c.465T>G p.S155= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV101079672; called by muse, varscan2
- EPS15 | c.180C>T p.A60= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs573768988, COSV100869046; called by muse, mutect2, varscan2
- ESRRB | c.261G>T p.S87= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99834812; called by muse, mutect2, varscan2
- ESYT2 | c.2289C>T p.P763= (on ENST00000613624; = p.P687= on NM_020728.3) | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV99276133; called by muse, mutect2, varscan2
- FGFR3 | c.810C>T p.D270= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs142910057; called by muse, mutect2, varscan2
- FOXD4L3 | c.963T>C p.D321= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as rs782373046, COSV100730980; called by muse, mutect2, varscan2
- GGTLC2 | c.321G>A p.S107= | Silent (SNP) | VAF 114/271 reads (42%) | catalogued as rs749153556, COSV101312179; called by muse, mutect2, varscan2
- HAO1 | c.795C>A p.L265= | Silent (SNP) | VAF 69/183 reads (38%) | catalogued as COSV101113132, COSV101113183; called by muse, mutect2, varscan2
- HMGCLL1 | c.81A>T p.S27= | Silent (SNP) | VAF 104/126 reads (83%) | catalogued as COSV99231464; called by muse, mutect2, varscan2
- HOXC11 | c.73C>A p.R25= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99678319; called by muse, mutect2, varscan2
- IGSF9B | c.2547C>G p.L849= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100317014, COSV58072700; called by muse, mutect2, varscan2
- KCNH7 | c.2688A>C p.S896= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100146948; called by muse, mutect2, varscan2
- KIAA1109 | c.11386C>A p.R3796= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99145882; called by muse, mutect2, varscan2
- KLK14 | c.513G>C p.P171= | Silent (SNP) | VAF 82/139 reads (59%) | catalogued as COSV99335670; called by muse, mutect2, varscan2
- KRT78 | c.90C>T p.F30= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100467113; called by muse, mutect2, varscan2
- LAMA2 | c.2778C>T p.F926= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV101370092; called by muse, mutect2, varscan2
- MAGEA8 | c.147C>A p.T49= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99674412; called by muse, mutect2, varscan2
- MOG | c.138G>T p.G46= | Silent (SNP) | VAF 106/377 reads (28%) | catalogued as COSV100972962, COSV65321185; called by muse, mutect2, varscan2
- MON2 | c.1179G>C p.L393= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99741663, COSV99741756; called by muse, mutect2, varscan2
- MUC16 | c.41691G>A p.L13897= | Silent (SNP) | VAF 83/135 reads (61%) | catalogued as COSV66695062; called by muse, mutect2, varscan2
- NAV3 | c.3849G>A p.A1283= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs757488888, COSV57103779; called by muse, mutect2, varscan2
- NCOA6 | c.2841G>A p.P947= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs1311728784, COSV100749910; called by muse, mutect2
- NPTN | c.672C>T p.S224= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV54740067; called by muse, mutect2, varscan2
- NUP93 | c.855G>T p.G285= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV100359933; called by muse, mutect2, varscan2
- OR10G7 | c.396C>A p.T132= | Silent (SNP) | VAF 23/310 reads (7%) | catalogued as rs1373143109, COSV100389769; called by muse, mutect2
- PCDHGA1 | c.2373A>G p.L791= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV100965929; called by muse, mutect2, varscan2
- PLXNA3 | c.4725G>A p.L1575= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as rs782613985, COSV100859814; called by muse, mutect2, varscan2
- PODXL | c.966A>G p.S322= (on ENST00000378555 / NM_001018111.3; = p.S290= on NM_005397.4) | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV100539239; called by muse, mutect2, varscan2
- PTGS1 | c.732G>T p.R244= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99792930; called by muse, mutect2, varscan2
- REM1 | c.537G>A p.L179= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs376535489; called by muse, mutect2, varscan2
- RYR1 | c.14292G>T p.G4764= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100614539; called by muse, mutect2, varscan2
- SCN9A | c.1923T>C p.N641= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs975387164, COSV100311471; called by muse, mutect2, varscan2
- SCRIB | c.720C>T p.G240= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs200348011, COSV100252600; called by muse, mutect2, varscan2
- SHOC1 | c.1206G>A p.T402= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs781179511, COSV100597285; called by muse, mutect2, varscan2
- SLC19A3 | c.210G>T p.V70= | Silent (SNP) | VAF 95/353 reads (27%) | catalogued as COSV99295648; called by muse, mutect2, varscan2
- TEPSIN | c.1449G>T p.V483= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100329534, COSV56145202; called by muse, mutect2, varscan2
- TRAV21 | c.273T>C p.R91= | Silent (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- TRIB3 | c.792G>A p.S264= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs765789298, COSV99423636; called by muse, mutect2, varscan2
- TRPC5 | c.1188G>A p.Q396= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as COSV99459394, COSV99463546; called by muse, mutect2, varscan2
- UNC13C | c.4614G>C p.A1538= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as COSV52840029, COSV99511969; called by muse, mutect2, varscan2
- USP44 | c.537A>G p.P179= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99311603; called by muse, mutect2, varscan2
- ZFHX4 | c.8802G>A p.T2934= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs200128741, COSV50677235, COSV50752892; called by muse, mutect2, varscan2
- ZIC4 | c.750C>T p.D250= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV101267828, COSV101267851, COSV67170767; called by muse, mutect2, varscan2
- ZNF449 | c.885G>A p.L295= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100202812; called by muse, mutect2, varscan2
- ZNF804A | c.636C>A p.I212= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV56440951, COSV56447572; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499010 C>T | 5'Flank (SNP) | VAF 67/261 reads (26%) | catalogued as rs376520805; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532305 C>G | 5'Flank (SNP) | VAF 32/53 reads (60%) | catalogued as COSV101587291; called by muse, mutect2, varscan2
- RORA | c.196+63651G>T | Intron (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99832187; called by muse, mutect2, varscan2
- RPL39 | c.108-745G>T | Intron (SNP) | VAF 44/121 reads (36%) | catalogued as COSV100846461; called by muse, mutect2, varscan2
- SSPOP | n.2521C>A | RNA (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100022147, COSV50487241; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2322G>A | Intron (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100313686; called by muse, mutect2, varscan2
- TTN | c.10360+4195G>T | Intron (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100595060, COSV60004631; called by muse, mutect2, varscan2
